Gene-level copy-number profile of tumor specimen TCGA-BR-8296-01A from TCGA case TCGA-BR-8296, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.9 years (21,527 days).
Specimen TCGA-BR-8296-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.095235f4-f9b4-4c44-a90e-2785497a6ec9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8296-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/231c9d28-46ed-4f56-88af-1f8f96e7a0bd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,256; copy number 2: 26,313; copy number 3: 24,495; copy number 4: 3,944; copy number 5: 1,800; copy number 9: 8; copy number 117: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8296-01A-11D-2338-01): tumor purity 0.24, ploidy 2.67, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,812 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:88,948,142–90,184,733, 8 genes, copy number 9: ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P.
- chr8:127,072,694–145,066,685, 342 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr10:121,410,916–121,713,994, 4 genes, copy number 117: RN7SKP167, FGFR2, AC009988.1, RPS15AP5.
- chr20:87,250–64,313,132, 1,458 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,256. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
